MMRF case MMRF_1474 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d7c8c72f-7ca5-44f2-a1ad-ca139df3ac07

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 27 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 27.8 years (10,136 days); ISS stage: II; Days to last known disease status: 1,327 days (3.6 years); Days to last follow up: 1,327 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 947 days (2.6 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 205 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 389 days (1.1 years); Days to treatment end: 1,030 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 526 days (1.4 years); Days to treatment end: 942 days (2.6 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,187 days (3.2 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,188 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 6.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.072 mg/dL; Immunoglobulin G 90.8 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 3.91 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 25 g/L; Total Protein 13.9 g/dL; Glucose 4.4 mmol/L; C-Reactive Protein 0.16 mg/dL.
- Day 85 (ECOG 0): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.556 mg/dL; Immunoglobulin G 20.3 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 332 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 4.35 mmol/L.
- Day 183 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.125 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 5.01 mmol/L.
- Day 260 (ECOG 0): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.667 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 9.15 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 4.79 mmol/L.
- Day 358 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.605 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 3.52 mmol/L.
- Day 449 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.562 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 7.9 g/dL; Glucose 5.45 mmol/L.
- Day 540 (ECOG 0): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.942 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 1.18 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 4.18 mmol/L.
- Day 631 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 8.58 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.89 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.24 mmol/L.
- Day 750 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.09 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Glucose 5.56 mmol/L.
- Day 848 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 6.05 mmol/L.
- Day 942 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.92 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 4.46 mmol/L.
- Day 1,030 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.17 mmol/L.
- Day 1,086 (ECOG 0): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 9.8 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 4.79 mmol/L.
- Day 1,173 (ECOG 1): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.17 mmol/L.
- Day 1,237 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.437 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 9.55 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 1,327 (ECOG 1): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.131 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -6: Weight: 89 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_1474_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1474_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
